Somatic mutation profile of tumor specimen MMRF_2198_1_BM_CD138pos (aliquot MMRF_2198_1_BM_CD138pos_T1_KHS5U_L08841) from MMRF case MMRF_2198, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 55.2 years (20,175 days).
Specimen MMRF_2198_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2a5d8832-4b85-45f7-9fe8-ed92fce7eb3b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2198_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2198_1_PB_Whole_C2_KHS5U_L08780; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c279fa56-7763-4413-bb21-f855fa3257e1

The open-access MAF lists 108 somatic variants for this specimen: 46 protein-altering or splice-affecting, 14 silent, 48 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, 3'UTR 18, Silent 14, Intron 10, 5'UTR 8, 3'Flank 7, 5'Flank 4, Nonsense Mutation 4, Frame Shift Ins 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 14/48 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PDHX | c.850C>T p.R284* | Nonsense Mutation (SNP) | VAF 49/177 reads (28%) | catalogued as rs143131258, COSV99927320; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 13/89 reads (15%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ADAMTS18 | c.2230G>A p.D744N | Missense Mutation (SNP) | VAF 17/128 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.167); catalogued as COSV51422997; called by muse, mutect2, varscan2
- ALDH16A1 | c.1262G>A p.G421E | Missense Mutation (SNP) | VAF 37/133 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.342); catalogued as rs1305453200; called by muse, mutect2, varscan2
- ATP10A | c.820G>A p.A274T | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.066); catalogued as rs774909568, COSV63513591, COSV63514871; called by muse, mutect2, varscan2
- CNTNAP3 | c.2006C>T p.A669V | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99905968; called by muse, mutect2
- COPS4 | c.349G>T p.E117* | Nonsense Mutation (SNP) | VAF 35/135 reads (26%) | catalogued as COSV52314745; called by muse, mutect2, varscan2
- DENND2B | c.389C>T p.A130V | Missense Mutation (SNP) | VAF 81/209 reads (39%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs1565763330; called by muse, mutect2, varscan2
- DNAH7 | c.6752G>A p.R2251H | Missense Mutation (SNP) | VAF 61/128 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs778541588, COSV56771368; called by muse, mutect2, varscan2
- DPP10 | c.2032A>G p.T678A | Missense Mutation (SNP) | VAF 19/139 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV59666602; called by muse, mutect2, varscan2
- FBXL18 | c.2141C>T p.P714L | Missense Mutation (SNP) | VAF 118/230 reads (51%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.823); catalogued as rs185800545; called by muse, mutect2, varscan2
- GRM1 | c.2050C>T p.R684C | Missense Mutation (SNP) | VAF 47/52 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763886921, COSV51110227; called by muse, mutect2, varscan2
- HCFC1 | c.2644A>G p.T882A | Missense Mutation (SNP) | VAF 60/60 reads (100%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.978); catalogued as COSV60073100; called by muse, mutect2, varscan2
- HEATR5A | c.1808G>A p.G603E | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66345862; called by muse, mutect2, varscan2
- IGHD6-13 | c.4T>C p.Y2H | Missense Mutation (SNP) | VAF 84/85 reads (99%) | catalogued as rs562173876; called by muse, mutect2, varscan2
- IGLV6-57 | c.302A>G p.K101R | Missense Mutation (SNP) | VAF 82/178 reads (46%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.006); catalogued as rs769648473; called by muse, varscan2
- ITGB7 | c.707C>T p.T236M | Missense Mutation (SNP) | VAF 12/143 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764841995; called by muse, mutect2
- MUC17 | c.4394C>T p.T1465M | Missense Mutation (SNP) | VAF 103/229 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs560666815, COSV100074961; called by muse, mutect2, varscan2
- MYO15A | c.1048G>A p.D350N | Missense Mutation (SNP) | VAF 76/460 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.038); catalogued as rs1222605746, COSV52756863; called by muse, mutect2, varscan2
- PIEZO2 | c.2960C>T p.T987I | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs1323885459; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCAPER | c.2102G>A p.R701Q | Missense Mutation (SNP) | VAF 25/161 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.428); catalogued as COSV57738869; called by muse, mutect2, varscan2
- SYN2 | c.527G>A p.R176Q | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as rs779119631, COSV70285266; called by muse, mutect2, varscan2
- TCAF2 | c.109G>A p.A37T | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.255); catalogued as rs1375527632; called by muse, mutect2
- ADCY5 | c.2095G>C p.E699Q | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- CAMSAP1 | c.2183C>G p.S728* | Nonsense Mutation (SNP) | VAF 111/323 reads (34%) | called by muse, mutect2, varscan2
- DDX5 | c.1394_1395dup p.A466Kfs*25 | Frame Shift Ins (INS) | VAF 19/66 reads (29%) | called by mutect2, pindel, varscan2
- ETV5 | c.1420C>T p.H474Y | Missense Mutation (SNP) | VAF 86/122 reads (70%) | SIFT tolerated (1); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- GNAS | c.157A>G p.K53E | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- H2AC17 | c.64G>C p.A22P | Missense Mutation (SNP) | VAF 52/117 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- HTRA1 | c.1312A>C p.N438H | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- IGLV4-60 | c.320A>G p.D107G | Missense Mutation (SNP) | VAF 40/101 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, varscan2
- IGLV4-69 | c.320A>T p.E107V | Missense Mutation (SNP) | VAF 51/111 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- LEKR1 | c.238A>T p.I80F | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.246); called by muse, mutect2
- NELFB | c.1550T>C p.L517P | Missense Mutation (SNP) | VAF 182/272 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- NFAT5 | c.3929A>G p.H1310R | Missense Mutation (SNP) | VAF 253/390 reads (65%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- NSD3 | c.4099T>C p.C1367R | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PLAUR | c.452G>A p.W151* | Nonsense Mutation (SNP) | VAF 10/148 reads (7%) | called by muse, mutect2
- PLXNA1 | c.1958C>T p.S653F | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- RNF130 | c.1233G>T p.L411F | Missense Mutation (SNP) | VAF 41/125 reads (33%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- SHPRH | c.3329G>A p.C1110Y (on ENST00000275233 / NM_001042683.3; = p.C1119Y on NM_173082.3) | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC25A34 | c.190G>C p.D64H | Missense Mutation (SNP) | VAF 41/92 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SPTBN2 | c.2955G>T p.Q985H | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SUPT6H | c.4291T>C p.Y1431H | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TEX15 | c.1108dup p.I370Nfs*7 (on ENST00000256246; = p.I753Nfs*7 on NM_001350162.2) | Frame Shift Ins (INS) | VAF 19/60 reads (32%) | called by mutect2, pindel, varscan2
- VPS33B | c.1555C>G p.P519A | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.215); called by muse, mutect2
- ANKRD11 | c.3159T>C p.D1053= | Silent (SNP) | VAF 19/189 reads (10%) | called by muse, mutect2
- CRTC2 | c.357C>T p.R119= | Silent (SNP) | VAF 3/12 reads (25%) | called by muse, mutect2
- DNAJA1 | c.96G>A p.K32= | Silent (SNP) | VAF 48/301 reads (16%) | called by muse, mutect2, varscan2
- EHD1 | c.1257C>T p.N419= | Silent (SNP) | VAF 90/281 reads (32%) | catalogued as rs747794386, COSV57735647; called by muse, mutect2, varscan2
- IGLV4-69 | c.162A>G p.A54= | Silent (SNP) | VAF 62/123 reads (50%) | catalogued as rs565429422; called by muse, mutect2, varscan2
- KCNT1 | c.3120G>A p.V1040= (on ENST00000488444; = p.V1066= on NM_020822.3) | Silent (SNP) | VAF 68/197 reads (35%) | catalogued as rs1277493926; called by muse, mutect2, varscan2
- MORC4 | c.2688T>A p.R896= | Silent (SNP) | VAF 40/152 reads (26%) | called by muse, mutect2, varscan2
- MYO3A | c.4704G>A p.Q1568= | Silent (SNP) | VAF 71/160 reads (44%) | catalogued as COSV56320704, COSV56322856; called by muse, mutect2, varscan2
- NEDD4 | c.1560T>C p.D520= (on ENST00000508342 / NM_001284338.1; = p.D101= on NM_006154.4) | Silent (SNP) | VAF 11/42 reads (26%) | called by muse, mutect2, varscan2
- PCDHB8 | c.81C>T p.G27= | Silent (SNP) | VAF 42/420 reads (10%) | called by muse, mutect2
- TDRD1 | c.1437C>T p.D479= | Silent (SNP) | VAF 10/41 reads (24%) | called by muse, mutect2, varscan2
- VMO1 | c.237G>A p.L79= | Silent (SNP) | VAF 92/187 reads (49%) | called by muse, mutect2, varscan2
- VWA2 | c.1026C>T p.V342= | Silent (SNP) | VAF 5/52 reads (10%) | catalogued as rs746874699; called by mutect2, varscan2
- ZFPM2 | c.144A>T p.T48= | Silent (SNP) | VAF 50/138 reads (36%) | called by muse, mutect2, varscan2
- ACADSB | c.*2009C>T | 3'UTR (SNP) | VAF 9/81 reads (11%) | called by muse, mutect2, varscan2
- ADAL | c.873+21T>G | Intron (SNP) | VAF 22/222 reads (10%) | called by muse, mutect2
- AMIGO1 | chr1:109504688 G>A | 3'Flank (SNP) | VAF 49/89 reads (55%) | called by muse, varscan2
- AMIGO1 | chr1:109504823 G>C | 3'Flank (SNP) | VAF 27/75 reads (36%) | called by muse, varscan2
- AMIGO1 | chr1:109504925 A>C | 3'Flank (SNP) | VAF 22/58 reads (38%) | called by muse, mutect2, varscan2
- AMIGO1 | chr1:109505402 G>C | 3'Flank (SNP) | VAF 16/44 reads (36%) | called by muse, varscan2
- APOBEC3F | c.172-652C>G | Intron (SNP) | VAF 60/126 reads (48%) | called by muse, mutect2, varscan2
- ARL13B | c.-12G>A | 5'UTR (SNP) | VAF 39/227 reads (17%) | catalogued as rs1197655754; called by muse, mutect2, varscan2
- BCL7A | chr12:122021462 G>A | 5'Flank (SNP) | VAF 59/95 reads (62%) | catalogued as rs958486224, COSV55847618, COSV55848399; called by muse, mutect2, varscan2
- CCDC39 | chr3:180679708 C>T | 5'Flank (SNP) | VAF 6/82 reads (7%) | catalogued as rs1364615545; called by muse, mutect2
- CDH18 | c.-70G>A | 5'UTR (SNP) | VAF 55/180 reads (31%) | called by muse, mutect2, varscan2
- CHM | c.*2843T>A | 3'UTR (SNP) | VAF 13/22 reads (59%) | called by muse, mutect2, varscan2
- CLDN16 | c.*1862C>T | 3'UTR (SNP) | VAF 18/59 reads (31%) | called by muse, mutect2, varscan2
- ETS1 | chr11:128460099 C>A | 3'Flank (SNP) | VAF 7/31 reads (23%) | catalogued as rs774630781; called by muse, varscan2
- FGF12 | c.-716C>G | 5'UTR (SNP) | VAF 40/153 reads (26%) | called by muse, mutect2, varscan2
- GAS7 | c.184-19863G>A | Intron (SNP) | VAF 19/36 reads (53%) | catalogued as rs1332117291; called by muse, mutect2, varscan2
- HGF | c.*27A>G | 3'UTR (SNP) | VAF 7/56 reads (13%) | called by muse, mutect2, varscan2
- JADE2 | c.*3037G>A | 3'UTR (SNP) | VAF 5/97 reads (5%) | called by muse, mutect2
- LRRC28 | c.168+3653A>G | Intron (SNP) | VAF 182/282 reads (65%) | called by muse, mutect2, varscan2
- MED13L | c.*2688G>C | 3'UTR (SNP) | VAF 8/44 reads (18%) | called by mutect2, varscan2
- PDP2 | c.*300G>A | 3'UTR (SNP) | VAF 23/85 reads (27%) | called by muse, mutect2, varscan2
- PHF7 | c.*57C>T | 3'UTR (SNP) | VAF 38/138 reads (28%) | catalogued as rs930668578; called by muse, mutect2, varscan2
- PIK3R5 | c.2206-86C>G | Intron (SNP) | VAF 25/48 reads (52%) | called by muse, mutect2, varscan2
- PLEKHG4B | chr5:140207 C>A | 5'Flank (SNP) | VAF 3/23 reads (13%) | catalogued as rs1280637280; called by muse, mutect2
- PLXNA4 | c.*6134C>T | 3'UTR (SNP) | VAF 59/135 reads (44%) | catalogued as rs375575755; called by muse, mutect2, varscan2
- POLB | c.-131A>G | 5'UTR (SNP) | VAF 89/176 reads (51%) | called by muse, mutect2, varscan2
- PPM1B | chr2:44233568 T>C | 3'Flank (SNP) | VAF 15/84 reads (18%) | called by muse, mutect2, varscan2
- RAB3C | c.*40G>A | 3'UTR (SNP) | VAF 48/143 reads (34%) | called by muse, mutect2, varscan2
- RAB3C | c.*6840C>G | 3'UTR (SNP) | VAF 19/84 reads (23%) | called by muse, mutect2, varscan2
- RN7SL319P | chr15:75782951 G>A | 5'Flank (SNP) | VAF 23/68 reads (34%) | catalogued as rs1470135894; called by muse, mutect2, varscan2
- SEC62 | c.*2631dup | 3'UTR (INS) | VAF 15/64 reads (23%) | catalogued as rs1188048880; called by mutect2, pindel, varscan2
- SLC25A34 | c.-211G>C | 5'UTR (SNP) | VAF 44/93 reads (47%) | called by muse, mutect2, varscan2
- SLC25A34 | c.-77G>C | 5'UTR (SNP) | VAF 71/162 reads (44%) | called by muse, varscan2
- SMIM11P1 | n.39T>C | RNA (SNP) | VAF 40/47 reads (85%) | called by muse, mutect2, varscan2
- STARD8 | c.-188G>T | 5'UTR (SNP) | VAF 46/46 reads (100%) | catalogued as rs760601528; called by muse, mutect2, varscan2
- SYT4 | c.*1293G>T | 3'UTR (SNP) | VAF 21/45 reads (47%) | catalogued as rs984686221; called by muse, mutect2, varscan2
- TBX20 | c.-444C>G | 5'UTR (SNP) | VAF 16/69 reads (23%) | called by muse, mutect2, varscan2
- TET2 | c.*1234T>A | 3'UTR (SNP) | VAF 8/29 reads (28%) | called by muse, mutect2, varscan2
- TMEM123 | c.157+553C>T | Intron (SNP) | VAF 52/175 reads (30%) | called by muse, mutect2, varscan2
- TMEM151B | c.*2327C>A | 3'UTR (SNP) | VAF 26/64 reads (41%) | called by muse, mutect2, varscan2
- TRMO | c.409+431G>C | Intron (SNP) | VAF 166/519 reads (32%) | called by muse, mutect2, varscan2
- TRPC6 | c.*273G>A | 3'UTR (SNP) | VAF 4/73 reads (5%) | called by muse, mutect2
- TTC9 | c.*2859G>T | 3'UTR (SNP) | VAF 27/54 reads (50%) | called by muse, mutect2, varscan2
- UGP2 | c.19+181A>G | Intron (SNP) | VAF 11/149 reads (7%) | called by muse, mutect2
- VCL | c.*314_*317del | 3'UTR (DEL) | VAF 27/211 reads (13%) | called by mutect2, pindel, varscan2
- Y_RNA | chr14:50091477 C>G | 3'Flank (SNP) | VAF 11/28 reads (39%) | called by muse, mutect2, varscan2
- ZNF443 | c.191+9C>T | Intron (SNP) | VAF 46/74 reads (62%) | catalogued as rs549664157; called by muse, mutect2, varscan2
- ZNF507 | c.2245+11A>C | Intron (SNP) | VAF 9/122 reads (7%) | called by muse, mutect2
